Somatic mutation profile of tumor specimen TCGA-DC-6158-01A (aliquot TCGA-DC-6158-01A-11D-1657-10) from TCGA case TCGA-DC-6158, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 70.8 years (25,842 days).
Specimen TCGA-DC-6158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08f60fdf-593e-4656-b40d-fb60b7e36c0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6158-10A (Blood Derived Normal), aliquot TCGA-DC-6158-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a547ed1b-2c0f-4cf1-825e-9e4d1008299f

The open-access MAF lists 89 somatic variants for this specimen: 65 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Nonsense Mutation 13, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 69/135 reads (51%) | catalogued as rs1211642532, CM994565, COSV57322919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 337/765 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 39/85 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3220C>A p.Q1074K | Missense Mutation (SNP) | VAF 131/239 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104404296, COSV59388545; called by muse, mutect2, varscan2
- ABLIM1 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as rs375611769; called by muse, mutect2, varscan2
- ADAMTS16 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs202209661; called by muse, mutect2, varscan2
- ANK2 | c.5758G>A p.G1920R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); catalogued as rs140189724, CM1511393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACH2 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.963); catalogued as rs898834968, COSV57597657, COSV57600876; called by muse, mutect2, varscan2
- CARF | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775019489, COSV57548232, COSV57548286; called by muse, mutect2, varscan2
- CCDC78 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs752010401, COSV52402029, COSV52402846; called by muse, mutect2, varscan2
- CFAP74 | c.1376G>A p.W459* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV54572196; called by muse, mutect2, varscan2
- CHML | c.1301T>G p.F434C | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59365094; called by muse, mutect2, varscan2
- CNTNAP2 | c.1826C>A p.S609* | Nonsense Mutation (SNP) | VAF 79/480 reads (16%) | catalogued as COSV100670874; called by muse, mutect2, varscan2
- DUOX1 | c.4575G>A p.M1525I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV52051279; called by muse, mutect2, varscan2
- EDAR | c.1221C>A p.S407R | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99304148; called by muse, mutect2, varscan2
- EXOSC4 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs201630396, COSV60156013; called by muse, mutect2, varscan2
- GPR157 | c.720G>A p.W240* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | catalogued as COSV66233929; called by muse, mutect2, varscan2
- HPGDS | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV54773545; called by muse, mutect2, varscan2
- KRTAP24-1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 168/268 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs200135144, COSV61089693; called by muse, mutect2, varscan2
- MAP7D3 | c.1087G>T p.E363* | Nonsense Mutation (SNP) | VAF 25/158 reads (16%) | catalogued as COSV60171416; called by muse, mutect2, varscan2
- MEGF10 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV99175484; called by muse, mutect2, varscan2
- MYH15 | c.4097A>T p.K1366M | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99844139; called by muse, mutect2
- MYO15A | c.6939C>A p.S2313R | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.57); PolyPhen benign (0.063); catalogued as COSV99234205; called by muse, mutect2, varscan2
- N4BP2L1 | c.377T>C p.M126T | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58413232; called by muse, mutect2, varscan2
- NEB | c.16294G>A p.A5432T | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.3); catalogued as rs988993094, COSV99427112; called by muse, mutect2, varscan2
- OLFM1 | c.1285C>A p.Q429K (on ENST00000371793 / NM_001282611.2; = p.Q411K on NM_014279.5) | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as COSV99424220; called by mutect2, varscan2
- OPRK1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 123/187 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs143457105; called by muse, mutect2, varscan2
- OTUD7A | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100193143; called by muse, mutect2, varscan2
- P4HA3 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV100525880; called by muse, mutect2, varscan2
- PBRM1 | c.3952G>A p.E1318K (on ENST00000296302 / NM_001366071.2; = p.E1293K on NM_018313.5) | Missense Mutation (SNP) | VAF 193/292 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as rs199643728; called by muse, mutect2, varscan2
- PCDHGA4 | c.2509del p.L837Ffs*45 | Frame Shift Del (DEL) | VAF 98/228 reads (43%) | catalogued as COSV53903053, COSV53972007, COSV99535801; called by mutect2, pindel, varscan2
- PCED1B | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs768597323, COSV71395107; called by muse, mutect2, varscan2
- PCIF1 | c.67T>G p.S23A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV100976112; called by muse, mutect2, varscan2
- PHIP | c.4081A>G p.M1361V | Missense Mutation (SNP) | VAF 101/246 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51506295; called by muse, mutect2, varscan2
- PIK3CG | c.2743del p.S915Pfs*30 | Frame Shift Del (DEL) | VAF 48/156 reads (31%) | catalogued as COSV63247931, COSV63249812; called by mutect2, pindel, varscan2
- PYGL | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV53586692; called by muse, mutect2, varscan2
- RIMS1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1479837493, COSV99325862; called by muse, mutect2
- RYR2 | c.8708T>C p.V2903A | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100772503; called by muse, mutect2, varscan2
- SCAPER | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 22/173 reads (13%) | catalogued as COSV57743238; called by muse, mutect2, varscan2
- SHPRH | c.1895G>C p.C632S | Missense Mutation (SNP) | VAF 45/315 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV51612151; called by muse, mutect2, varscan2
- SLC14A1 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs1460927307, COSV100425212; called by muse, mutect2, varscan2
- SLC16A7 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 37/586 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs543596862, COSV53893187, COSV53900554; called by muse, mutect2
- SPATA13 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371749849; called by muse, mutect2, varscan2
- STAT1 | c.623A>G p.N208S | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV61189993; called by muse, mutect2, varscan2
- SYNE1 | c.24050C>A p.S8017Y (on ENST00000367255 / NM_182961.4; = p.S7946Y on NM_033071.3) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54902801; called by muse, mutect2, varscan2
- TNNI3 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV99403001; called by muse, mutect2, varscan2
- TRPV6 | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV63892249; called by muse, mutect2, varscan2
- TTLL12 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.42); catalogued as rs746660164, COSV53355748; called by muse, mutect2, varscan2
- UHRF1BP1L | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54439043; called by muse, mutect2, varscan2
- ZBTB8A | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100331462; called by muse, mutect2, varscan2
- ZNF385D | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 370/648 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55761185; called by muse, mutect2, varscan2
- ZNF493 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 80/461 reads (17%) | catalogued as rs768428975, COSV62750534; called by muse, mutect2, varscan2
- ZNF493 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV62750551; called by muse, varscan2
- ZNF493 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV62750557; called by muse, varscan2
- ZNF493 | c.617C>G p.S206* | Nonsense Mutation (SNP) | VAF 51/228 reads (22%) | catalogued as COSV62750568; called by muse, varscan2
- ZNF493 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 45/202 reads (22%) | catalogued as COSV62750573, COSV62753014; called by muse, varscan2
- ZNF493 | c.811C>G p.H271D | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62749873, COSV62750577; called by muse, varscan2
- ZNF493 | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62750584; called by muse, mutect2, varscan2
- ZNF714 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 56/268 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99395509; called by muse, varscan2
- ZNF714 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 68/334 reads (20%) | catalogued as rs1267162942, COSV52512813; called by muse, varscan2
- ZNF714 | c.583C>G p.H195D | Missense Mutation (SNP) | VAF 48/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377506115; called by muse, varscan2
- ZNF714 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV52512880; called by muse, varscan2
- ZNF714 | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52512897, COSV52514332; called by muse, varscan2
- ZNF714 | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV52512927; called by muse, varscan2
- NAALADL2 | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- A2M | c.3219G>A p.R1073= | Silent (SNP) | VAF 129/238 reads (54%) | catalogued as COSV59388553; called by muse, mutect2, varscan2
- ANKRD17 | c.6111C>T p.H2037= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100429865; called by muse, mutect2, varscan2
- APCDD1L | c.915C>T p.H305= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs755841775, COSV64486872, COSV64487185; called by muse, mutect2, varscan2
- B4GALT4 | c.237T>A p.S79= | Silent (SNP) | VAF 104/171 reads (61%) | catalogued as COSV63296013; called by muse, mutect2, varscan2
- CLCN1 | c.1365C>T p.N455= | Silent (SNP) | VAF 30/536 reads (6%) | catalogued as rs779313772, COSV100578447; called by muse, mutect2
- DLEC1 | c.1716C>T p.I572= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV57295701; called by muse, mutect2, varscan2
- DYSF | c.5067G>A p.P1689= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs750640522, COSV50454937, COSV99247944; ClinVar: likely benign; called by muse, mutect2
- FOXI2 | c.783C>T p.T261= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs748678951, COSV59094607; called by muse, mutect2, varscan2
- GAS6 | c.1245A>G p.G415= | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs1183322938, COSV100582171; called by muse, mutect2, varscan2
- KANK2 | c.741G>A p.E247= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV62008713; called by muse, mutect2, varscan2
- LDB2 | c.240C>T p.I80= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs546170586, COSV58772531; called by muse, mutect2
- MYT1L | c.2496C>T p.D832= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs562364952, COSV67719400; called by muse, mutect2, varscan2
- NCKAP1L | c.1692T>C p.Y564= | Silent (SNP) | VAF 256/510 reads (50%) | catalogued as rs540937692, COSV53208486; called by muse, mutect2, varscan2
- NOVA1 | c.75G>A p.S25= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV57480108; called by muse, mutect2, varscan2
- NYAP2 | c.1152G>A p.P384= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as rs767320947, COSV56008842; called by muse, mutect2, varscan2
- PARN | c.807A>G p.G269= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100421335; called by muse, mutect2, varscan2
- PRKAG2 | c.201C>T p.F67= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs759893229, COSV55232475; ClinVar: likely benign; called by muse, mutect2, varscan2
- RLBP1 | c.471G>T p.V157= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV99175389; called by muse, mutect2, varscan2
- SYT12 | c.948G>A p.K316= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV67354320; called by muse, mutect2, varscan2
- TEX15 | c.6666T>C p.D2222= (on ENST00000256246; = p.D2605= on NM_001350162.2) | Silent (SNP) | VAF 134/314 reads (43%) | catalogued as COSV56348286; called by muse, mutect2, varscan2
- USP11 | c.1845C>T p.H615= (on ENST00000218348; = p.H572= on NM_001371072.1) | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV54474231; called by muse, mutect2, varscan2
- ZNF714 | c.831C>T p.F277= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as COSV52512868; called by muse, varscan2
- HERC2P3 | n.1634G>A | RNA (SNP) | VAF 34/307 reads (11%) | catalogued as rs775514377; called by muse, mutect2, varscan2
- STAG3L2 | n.761C>T | RNA (SNP) | VAF 121/531 reads (23%) | catalogued as rs1172288001; called by muse, mutect2, varscan2
